Somatic mutation profile of tumor specimen TCGA-06-1084-01A (aliquot TCGA-06-1084-01A-01W-0611-08) from TCGA case TCGA-06-1084, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.5 years (19,899 days).
Specimen TCGA-06-1084-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3e693ab-bfa1-47d3-a016-6607bbcf09d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-1084-10A (Blood Derived Normal), aliquot TCGA-06-1084-10A-01W-0611-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c096fc52-ada4-4592-9407-773816340d21

The open-access MAF lists 85 somatic variants for this specimen: 66 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 17, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 1, Intron 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2084T>C p.L695P | Missense Mutation (SNP) | VAF 172/462 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199474761, CM000787, CM096911, COSV100648305; ClinVar: pathogenic / not provided; called by muse, varscan2
- RXYLT1 | c.279del p.G94Efs*33 | Frame Shift Del (DEL) | VAF 13/113 reads (12%) | catalogued as rs397514546; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACACB | c.3922A>T p.S1308C | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as COSV100622892, COSV100623307; called by muse, mutect2
- ACADS | c.134G>C p.C45S | Missense Mutation (SNP) | VAF 204/1274 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99656851; called by muse, mutect2, varscan2
- ANKRD12 | c.6181C>G p.P2061A | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100042128; called by muse, mutect2
- ARHGAP9 | c.2044C>T p.H682Y (on ENST00000393797 / NM_001319850.2; = p.H663Y on NM_032496.4) | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV99954728; called by muse, mutect2, varscan2
- ART1 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as COSV99167261; called by muse, mutect2, varscan2
- BSPRY | c.737C>A p.S246* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99445148; called by muse, mutect2
- CALCOCO1 | c.156+1G>T p.X52_splice | Splice Site (SNP) | VAF 11/367 reads (3%) | catalogued as COSV100017498; called by muse, mutect2
- CCAR2 | c.1227G>T p.Q409H | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as COSV52385449, COSV99374328; called by muse, mutect2
- CFAP43 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV99531020; called by muse, mutect2, varscan2
- CHD8 | c.7442C>T p.P2481L (on ENST00000646647 / NM_001170629.2; = p.P2202L on NM_020920.4) | Missense Mutation (SNP) | VAF 55/91 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99360226; called by muse, mutect2, varscan2
- CYP19A1 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 158/1804 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99548153; called by muse, mutect2
- E2F8 | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.215); catalogued as COSV100001774, COSV100001846; called by muse, mutect2, varscan2
- EGR2 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 12/235 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV99654309; called by muse, mutect2
- ERCC6L | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV100559267; called by muse, mutect2
- ERN1 | c.1880G>T p.R627L | Missense Mutation (SNP) | VAF 30/710 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101458576, COSV70504365; called by muse, mutect2
- FCRL5 | c.1328C>A p.S443* | Nonsense Mutation (SNP) | VAF 18/456 reads (4%) | catalogued as COSV100709331; called by muse, mutect2
- GABRA5 | c.37A>G p.K13E | Missense Mutation (SNP) | VAF 32/362 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV100165787; called by muse, mutect2
- GRIN2A | c.2672A>G p.Q891R | Missense Mutation (SNP) | VAF 334/1229 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100411097; called by muse, mutect2, varscan2
- GTF2E2 | c.304A>G p.I102V | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV100577171; called by muse, mutect2, varscan2
- HAVCR2 | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100324997; called by muse, mutect2, varscan2
- IFI16 | c.549G>C p.E183D | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as COSV99858200; called by muse, mutect2, varscan2
- IL17RB | c.176C>A p.T59K | Missense Mutation (SNP) | VAF 30/674 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0.023); catalogued as COSV99861352; called by muse, mutect2
- KDR | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 82/504 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs551579207, COSV55757831, COSV55763620; called by muse, mutect2, varscan2
- MAGEA12 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.284); catalogued as rs1275808859, COSV100757057; called by muse, mutect2
- MAGEC2 | c.361G>T p.G121W | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV55997711, COSV55998813; called by muse, mutect2, varscan2
- MAML3 | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 123/933 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100505508; called by muse, mutect2, varscan2
- MS4A1 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 78/503 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs201665706, COSV100619431; called by muse, mutect2, varscan2
- MUC16 | c.15914T>A p.F5305Y | Missense Mutation (SNP) | VAF 74/434 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.192); catalogued as COSV101201748; called by muse, mutect2, varscan2
- NCBP2 | c.451A>G p.K151E | Missense Mutation (SNP) | VAF 84/310 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV100052286; called by muse, mutect2, varscan2
- NRXN2 | c.3657A>G p.I1219M | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV99635850; called by muse, mutect2, varscan2
- OR2T33 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs368660679; called by muse, mutect2, varscan2
- OR6Y1 | c.655G>C p.V219L | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100225504; called by muse, mutect2, varscan2
- OSGIN2 | c.482A>T p.K161I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV99858705; called by muse, mutect2
- PALB2 | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV99848994; called by muse, mutect2
- PDE11A | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 31/592 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1364144029, COSV99615032; called by muse, mutect2
- PDE6A | c.2015C>T p.A672V | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1420699331, COSV99678734; called by muse, mutect2, varscan2
- PDLIM5 | c.92C>G p.S31C | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100524375; called by muse, mutect2, varscan2
- PIK3C2B | c.3907C>G p.L1303V | Missense Mutation (SNP) | VAF 23/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100916226; called by muse, mutect2
- PLRG1 | c.551C>A p.T184K | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100123259; called by muse, mutect2
- PPP1R9A | c.1477C>A p.L493I | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99198726; called by muse, mutect2, varscan2
- PTEN | c.134T>A p.V45E | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100911352, COSV64296708; called by muse, mutect2, varscan2
- RBM27 | c.1773C>A p.F591L | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99506643; called by muse, mutect2, varscan2
- SAP130 | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 91/336 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99385331; called by muse, mutect2, varscan2
- SARAF | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.92); PolyPhen benign (0.212); catalogued as COSV99822921; called by muse, mutect2
- SLC5A3 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 61/363 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as COSV62968601; called by muse, mutect2, varscan2
- SLC8A3 | c.518G>T p.S173I | Missense Mutation (SNP) | VAF 24/536 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100776385; called by muse, mutect2
- SMC1A | c.1867G>C p.E623Q | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100447682; called by mutect2, varscan2
- SPTA1 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 75/315 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as rs775896025, COSV100935510, COSV63748678; called by muse, mutect2, varscan2
- SRSF11 | c.683A>G p.E228G | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs201108984, COSV100918022; called by muse, mutect2
- STC2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV99438714; called by muse, mutect2, varscan2
- SUMO1 | c.60A>C p.E20D | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV66261089; called by muse, mutect2, varscan2
- TAB3 | c.738G>T p.Q246H | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99916841; called by muse, mutect2
- TMEM39A | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as rs559521023, COSV59900506; called by muse, mutect2, varscan2
- TMPRSS6 | c.1391C>G p.A464G | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100696164; called by muse, mutect2
- TRHDE | c.2719C>G p.L907V | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53834146, COSV99672578; called by muse, mutect2, varscan2
- TRPV2 | c.670G>C p.V224L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV100641370, COSV58428565; called by muse, mutect2, varscan2
- TTN | c.86117C>A p.A28706D (on ENST00000591111; = p.A21282D on NM_003319.4) | Missense Mutation (SNP) | VAF 13/352 reads (4%) | PolyPhen probably damaging (0.976); catalogued as COSV100630482; called by muse, mutect2
- TTN | c.18083G>A p.S6028N (on ENST00000591111; = p.S5101N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/447 reads (13%) | PolyPhen benign (0); catalogued as COSV100630483; called by muse, mutect2, varscan2
- UGT2A3 | c.632del p.N211Ifs*28 | Frame Shift Del (DEL) | VAF 34/182 reads (19%) | catalogued as COSV52360084; called by mutect2, pindel, varscan2
- WDR24 | c.599G>A p.S200N (on ENST00000248142; = p.S138N on NM_032259.4) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99556015; called by muse, mutect2, varscan2
- ZMYND11 | c.991A>G p.N331D | Missense Mutation (SNP) | VAF 104/596 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.422); catalogued as COSV100556933; called by muse, mutect2, varscan2
- ZNF337 | c.2123C>T p.T708I | Missense Mutation (SNP) | VAF 57/419 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.662); catalogued as rs1296416009, COSV99430463; called by muse, mutect2, varscan2
- ZNF45 | c.1691G>T p.G564V | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV99524270; called by muse, mutect2
- TLK1 | c.1216dup p.R406Kfs*17 | Frame Shift Ins (INS) | VAF 6/62 reads (10%) | called by mutect2, varscan2
- AGXT | c.162C>T p.Y54= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100280387; called by muse, mutect2, varscan2
- AHNAK | c.6891C>G p.G2297= | Silent (SNP) | VAF 32/262 reads (12%) | catalogued as rs1313827274; called by muse, mutect2
- AMDHD1 | c.630C>T p.N210= | Silent (SNP) | VAF 20/168 reads (12%) | catalogued as COSV99900527; called by muse, mutect2, varscan2
- FLG | c.3105C>T p.S1035= | Silent (SNP) | VAF 18/585 reads (3%) | called by muse, mutect2
- HNF1A | c.1263C>G p.S421= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99983025; called by muse, mutect2, varscan2
- KLHDC10 | c.804C>T p.D268= | Silent (SNP) | VAF 25/274 reads (9%) | catalogued as rs755556916, COSV100111042; called by muse, mutect2
- KSR2 | c.2268C>T p.I756= | Silent (SNP) | VAF 90/536 reads (17%) | catalogued as COSV56665231, COSV56677971; called by muse, mutect2, varscan2
- METTL21A | c.123A>T p.G41= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV99777783; called by muse, mutect2
- MRPL24 | c.192C>A p.I64= | Silent (SNP) | VAF 7/166 reads (4%) | catalogued as COSV100625913; called by muse, mutect2
- MYLK4 | c.459C>T p.S153= | Silent (SNP) | VAF 292/1070 reads (27%) | catalogued as rs1216094215, COSV99193901; called by muse, mutect2, varscan2
- NR2C2 | c.1293G>T p.L431= (on ENST00000393102; = p.L450= on NM_003298.5) | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as COSV100038884; called by muse, mutect2
- PLPP2 | c.669C>T p.S223= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as rs751907540, COSV99514830; called by muse, varscan2
- PPIL1 | c.417G>A p.V139= | Silent (SNP) | VAF 43/314 reads (14%) | catalogued as COSV101033944; called by muse, mutect2, varscan2
- ROCK1 | c.309T>C p.A103= | Silent (SNP) | VAF 39/191 reads (20%) | catalogued as COSV101296627; called by muse, mutect2, varscan2
- SLCO6A1 | c.132C>T p.P44= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1561509974, COSV65809551; called by muse, mutect2, varscan2
- SRPX | c.1203G>T p.L401= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100656260; called by mutect2, varscan2
- SUN3 | c.558T>C p.D186= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99814385; called by muse, mutect2, varscan2
- FGFR1 | c.937-1112G>C | Intron (SNP) | VAF 55/207 reads (27%) | catalogued as COSV100249283; called by muse, mutect2, varscan2
- SNORD116-17 | n.61T>A | RNA (SNP) | VAF 95/476 reads (20%) | called by muse, mutect2, varscan2
